Gene-level copy-number profile of tumor specimen C3L-03678-02 from CPTAC case C3L-03678, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 49.9 years (18,220 days).
Specimen C3L-03678-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6e3d3f79-aba2-4a63-8305-6c52462a4e0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-03678-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/4311ca95-a9af-4c88-9894-aa5e22da8242

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 461; copy number 1: 13,051; copy number 2: 40,219; copy number 3: 4,332; copy number 4: 352; copy number 5: 135; copy number 6: 104; copy number 7: 25; copy number 9: 20; copy number 10: 46; copy number 11: 4; copy number 12: 3; copy number 14: 125; copy number 15: 1; copy number 18: 5.

Homozygous deletions (total copy number 0; autosomes only): 113 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr9:20,658,309–28,670,286, 110 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 468 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:181,847,526–184,017,939, 46 genes, copy number 5–14: AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24, YEATS2, YEATS2-AS1, AC131160.1, MAP6D1, PARL, RPSAP31, MIR4448, CYP2AB1P, ABCC5, ABCC5-AS1.
- chr8:37,326,575–40,897,833, 87 genes, copy number 5–15 (broad region; genes not listed).
- chr8:41,426,655–43,363,518, 64 genes, copy number 5 (broad region; genes not listed).
- chr9:28,863,626–29,826,711, 6 genes, copy number 5–6: MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr13:19,422,877–20,232,365, 24 genes, copy number 7: TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2, KRR1P1, AL138688.2, LINC01072, GJA3, PPIAP28, LINC00556, GJB2, AL138688.1, GJB6.
- chr16:23,278,231–24,911,628, 39 genes, copy number 5–18: SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2, NDUFAB1, PALB2, AC008870.4, DCTN5, AC008870.1, PLK1, AC008870.3, ERN2, AC008870.5, AC012317.1, AC012317.2, CHP2, PRKCB, AC130454.1, AC130448.1, MIR1273H, AC130448.2, LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11.
- chr16:27,459,555–30,670,810, 202 genes, copy number 6–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
